TCGA case TCGA-A2-A0CK — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5aca16ca-4516-4e27-8249-6914029a7ebf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,094 days); Year of diagnosis: 2001; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 20; Micrometastasis present: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 243 days; Days to treatment end: 280 days; Treatment dose: 5,040 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 1,451 days (4.0 years); Days to treatment end: 1,518 days (4.2 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: 1,569 days (4.3 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nelipepimut-S; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 64.2 years (23,458 days); Days to diagnosis: 1,364 days (3.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,409 days (3.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 3,820 days (10.5 years); Disease response: Tumor Free.
- Days to follow up: 4,159 days (11.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): 1.2; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Negative.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 2+; Test value range: 40-49%.
- ESR1 (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 2+; Test value range: 50-59%.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 1+; Test value range: 10-19%.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 3+; Test value range: 80-89%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A0CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-A2-A0CK-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A0CK-01A-01-BSA: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 57; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A0CK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A0CK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Her2 cent17 ratio: 1.1; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Lumpectomy; Surgery for positive margins: Modified radical mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Er IHC score: 2+; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Left breast; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event cent 17 her2 ratio: 1.2.
- Drug treatment 1: Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 6: Pharmaceutical therapy drug name: E-75.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,159 days; disease-specific survival: no event (censored), 4,159 days; disease-free interval: event (new tumor event after initially disease-free), 1,364 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,364 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A0CK-01A-11D-A227-01): tumor purity 0.69, ploidy 1.99, whole-genome doublings 0.
